Somatic mutation profile of tumor specimen TCGA-67-6216-01A (aliquot TCGA-67-6216-01A-11D-1753-08) from TCGA case TCGA-67-6216, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 57.4 years (20,967 days).
Specimen TCGA-67-6216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8892a894-2f26-45a0-bd4d-40324e92186e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-6216-10A (Blood Derived Normal), aliquot TCGA-67-6216-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f412ba5-ecf7-4c9a-80a5-4250f6400957

The open-access MAF lists 29 somatic variants for this specimen: 25 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Nonsense Mutation 3, Silent 3, Frame Shift Del 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC12 | c.2006A>T p.D669V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60917624; called by muse, mutect2, varscan2
- CRACD | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV51730239; called by muse, mutect2
- CROT | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV58976496; called by muse, mutect2
- CRYBB1 | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.5); catalogued as COSV53234615; called by muse, mutect2
- DEAF1 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV58609070; called by muse, mutect2, varscan2
- EME1 | c.25T>C p.S9P | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.641); catalogued as COSV99869176; called by muse, mutect2
- EXOC3L4 | c.1859C>G p.S620C | Missense Mutation (SNP) | VAF 10/137 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101197735; called by muse, mutect2
- LPIN2 | c.250G>C p.G84R | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55243562; called by muse, mutect2
- MLST8 | c.931C>T p.H311Y | Missense Mutation (SNP) | VAF 23/258 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57030996; called by muse, mutect2
- MUC16 | c.20804C>T p.S6935F | Missense Mutation (SNP) | VAF 77/318 reads (24%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.076); catalogued as rs751145832, COSV67456560, COSV67481753; called by muse, mutect2, varscan2
- MYCT1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.306); catalogued as COSV65891853; called by muse, mutect2, varscan2
- NUP98 | c.4838C>T p.A1613V (on ENST00000359171 / NM_001365126.1; = p.A1596V on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.273); catalogued as COSV61437676; called by muse, mutect2, varscan2
- PI4KB | c.1955A>G p.N652S (on ENST00000368873 / NM_001369623.1; = p.N664S on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/234 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV55020898; called by muse, mutect2
- PRIM1 | c.1150A>T p.K384* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100590501; called by muse, mutect2, varscan2
- PTBP1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.701); catalogued as COSV62461555; called by muse, mutect2
- SETD2 | c.6199A>T p.K2067* | Nonsense Mutation (SNP) | VAF 128/457 reads (28%) | catalogued as COSV57448964; called by muse, mutect2, varscan2
- SHPRH | c.1519A>T p.T507S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as COSV51616349; called by muse, mutect2
- SLFN12 | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV59227427; called by muse, mutect2
- USH2A | c.2779C>T p.Q927* | Nonsense Mutation (SNP) | VAF 8/150 reads (5%) | catalogued as rs1438734382, COSV56424398; called by muse, mutect2
- ZDHHC15 | c.717C>G p.S239R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.864); catalogued as COSV64903511; called by muse, mutect2
- ZNF331 | c.11G>A p.G4D | Missense Mutation (SNP) | VAF 48/641 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1246230912, COSV53479527; called by muse, mutect2
- ZNF780A | c.790C>T p.L264F | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.524); catalogued as rs764400076, COSV100575275; called by muse, mutect2, varscan2
- ACACB | c.6546del p.R2183Dfs*8 | Frame Shift Del (DEL) | VAF 43/163 reads (26%) | called by mutect2, pindel, varscan2
- ATF6 | c.1310del p.N437Tfs*15 | Frame Shift Del (DEL) | VAF 36/148 reads (24%) | called by mutect2, pindel, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 15/131 reads (11%) | called by mutect2, pindel, varscan2
- DAPK1 | c.240C>T p.H80= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as rs36207429, COSV63783823; called by muse, mutect2, varscan2
- HMGCR | c.870A>G p.S290= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1230896412, COSV99843514; called by muse, mutect2
- TRIP4 | c.1524G>T p.L508= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as COSV56033122; called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668356 C>G | 5'Flank (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
